Somatic mutation profile of tumor specimen TCGA-LN-A7HW-01A (aliquot TCGA-LN-A7HW-01A-22D-A351-09) from TCGA case TCGA-LN-A7HW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 59.8 years (21,840 days).
Specimen TCGA-LN-A7HW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 214c02bb-9659-4c63-90fe-3413a1e92666.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A7HW-10A (Blood Derived Normal), aliquot TCGA-LN-A7HW-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89ba268a-9035-4415-b6c9-1697b791cb41

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 69, Silent 23, Nonsense Mutation 2, In Frame Del 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 104/261 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 99/119 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.6368C>G p.S2123C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.87); catalogued as rs772435969; called by muse, mutect2, varscan2
- BAZ2A | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as rs369013055; called by muse, mutect2, varscan2
- BSN | c.10913G>A p.R3638H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs147167809; called by muse, mutect2, varscan2
- CCDC88B | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.699); catalogued as rs1022274214, COSV57265531; called by muse, mutect2, varscan2
- CEACAM18 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs371514477, COSV67282652; called by muse, mutect2, varscan2
- DCC | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1195383149; called by muse, mutect2, varscan2
- DMTN | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs781626631, COSV99741527; called by muse, mutect2
- E2F1 | c.1173C>G p.F391L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as rs1333288110; called by muse, mutect2, varscan2
- EEF1G | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240404; called by muse, mutect2, varscan2
- ESRP2 | c.1558G>A p.D520N (on ENST00000565858 / NM_001365264.1; = p.D510N on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs374057525; called by muse, mutect2, varscan2
- FOXL2NB | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs779660003, COSV57728178; called by muse, mutect2, varscan2
- GGA3 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs776432859; called by muse, mutect2, varscan2
- IRGQ | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750405377, COSV60671372; called by muse, varscan2
- LGR6 | c.488C>T p.S163F (on ENST00000367278 / NM_001017403.1; = p.S111F on NM_021636.3) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV55152606; called by muse, mutect2, varscan2
- MYO6 | c.2389C>G p.Q797E | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV64117847; called by muse, mutect2, varscan2
- PCDH11X | c.3128G>A p.G1043E | Missense Mutation (SNP) | VAF 91/125 reads (73%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.483); catalogued as rs1165382562; called by muse, mutect2, varscan2
- PIGT | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376655698, COSV54125643; called by muse, mutect2
- PLXNA4 | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1026475114; called by muse, mutect2, varscan2
- PPP2R5B | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV51210430; called by muse, mutect2, varscan2
- PRL | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as rs779422396, COSV60591695; called by muse, mutect2, varscan2
- PXMP4 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs923665493; called by muse, mutect2, varscan2
- ROCK2 | c.3860C>T p.P1287L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59962379; called by muse, mutect2, varscan2
- SCN1A | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as rs1434950269, CM104355, COSV57665359; called by muse, mutect2, varscan2
- SIPA1 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100425882; called by muse, mutect2, varscan2
- TMEM182 | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68425480; called by muse, mutect2, varscan2
- USF3 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1192058956, COSV57077456; called by muse, mutect2, varscan2
- ZFC3H1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as rs1470282107; called by muse, mutect2, varscan2
- ABCB11 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGBL2 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP000812.4 | c.21G>C p.K7N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BRIX1 | c.208A>T p.I70L | Missense Mutation (SNP) | VAF 186/287 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CATSPER1 | c.442C>G p.H148D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CCDC146 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CDCA2 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH10 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP162 | c.2425A>C p.K809Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHRM3 | c.1565C>G p.P522R | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL28A1 | c.2395C>A p.L799M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND1 | c.806G>C p.S269T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDX50 | c.1758G>A p.G586= | Splice Region (SNP) | VAF 37/62 reads (60%) | called by muse, mutect2, varscan2
- DGCR6L | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DIS3 | c.2877G>T p.*959Yext*14 | Nonstop Mutation (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- DNAH9 | c.6970A>C p.T2324P | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPAS1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GOLGA6L9 | c.965A>G p.E322G | Missense Mutation (SNP) | VAF 39/564 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2
- H3C8 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | called by muse, mutect2, varscan2
- HNRNPLL | c.1306A>T p.N436Y | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF13B | c.3515T>C p.V1172A | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.11982C>A p.F3994L | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LTBP4 | c.683A>G p.Q228R (on ENST00000308370 / NM_001042544.1; = p.Q191R on NM_003573.2) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MGAM | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.22570C>A p.P7524T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); called by muse, mutect2
- OMA1 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 31/41 reads (76%) | called by muse, mutect2, varscan2
- PNMA1 | c.929T>A p.L310H | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POSTN | c.276C>G p.C92W | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMM50 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SDHA | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 159/269 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SECISBP2 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIPA1 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SLC4A5 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SON | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA18 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SPATA25 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TECTB | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIP11 | c.3811A>T p.I1271F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- UNC79 | c.1183C>A p.R395S (on ENST00000393151 / NM_001346218.2; = p.R218S on NM_020818.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USHBP1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- XYLB | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2
- YOD1 | c.902_904del p.A301del | In Frame Del (DEL) | VAF 27/53 reads (51%) | called by mutect2, pindel, varscan2
- ZNF385B | c.434T>A p.F145Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF618 | c.1819G>A p.V607M (on ENST00000374126 / NM_001318042.2; = p.V514M on NM_133374.2) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL7C | c.438G>A p.E146= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- BRAP | c.57C>T p.P19= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- DCAF15 | c.1350C>T p.F450= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs778091615; called by muse, mutect2, varscan2
- DPYS | c.1242C>A p.I414= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV60910631; called by muse, mutect2
- DUOX1 | c.3285C>T p.F1095= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV58476894; called by muse, mutect2, varscan2
- E2F1 | c.1296C>T p.L432= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs752347181; called by muse, mutect2, varscan2
- FAHD2B | c.762C>T p.F254= | Silent (SNP) | VAF 56/172 reads (33%) | called by muse, mutect2, varscan2
- GPATCH1 | c.2490C>T p.F830= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs770047387, COSV50112027; called by muse, mutect2, varscan2
- HIVEP1 | c.7990C>T p.L2664= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV65105013; called by muse, mutect2, varscan2
- KLK15 | c.315C>T p.N105= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs369380000, COSV56826422; called by muse, mutect2, varscan2
- KRTAP20-1 | c.45G>T p.G15= | Silent (SNP) | VAF 91/134 reads (68%) | catalogued as COSV100228703; called by muse, mutect2, varscan2
- MTG2 | c.855C>A p.G285= | Silent (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- NOVA2 | c.630C>G p.L210= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99611377; called by muse, mutect2, varscan2
- NUP188 | c.4821C>T p.F1607= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as rs755350781, COSV65330159; called by muse, mutect2, varscan2
- OR13C3 | c.756C>G p.L252= | Silent (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- OR2AT4 | c.756C>A p.V252= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- PIRT | c.354G>A p.Q118= | Silent (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- PKD1 | c.5025C>T p.A1675= | Silent (SNP) | VAF 72/120 reads (60%) | called by muse, mutect2, varscan2
- PRKD2 | c.1431C>T p.F477= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs763789755, COSV52187968; called by muse, mutect2, varscan2
- SUN5 | c.412C>T p.L138= | Silent (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- USH2A | c.9735A>G p.L3245= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as rs1264688863; called by muse, mutect2, varscan2
- VANGL2 | c.627G>A p.E209= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- ZNF785 | c.879C>T p.F293= | Silent (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
